Gene-level copy-number profile of tumor specimen ALCH-B2RM-TTP1-A from ALCHEMIST case ALCH-B2RM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.7 years (22,168 days).
Specimen ALCH-B2RM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 07b0f183-c7ea-4bb2-9677-09bf8c00ec46.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2RM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/236eeee9-bb95-4dfd-9fa2-fe05267ff236

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 9,579; copy number 2: 45,301; copy number 3: 3,451; copy number 4: 7; copy number 5: 1; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,442,034–232,460,753, 2 genes: DIS3L2P1, ALPI.
- chr6:168,053,166–168,101,511, 1 gene: FRMD1.
- chr6:170,199,769–170,200,258, 1 gene: RPL12P23.
- chr11:369,499–382,117, 1 gene: B4GALNT4.
- chr12:2,659,937–2,691,200, 3 genes (within-gene range 0–1): AC007618.1, CACNA1C-AS2, CACNA1C-AS1.
- chr15:25,169,337–25,243,695, 41 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40.
- chr15:89,358,841–89,398,487, 4 genes: AC133637.1, AC133637.2, MIR9-3HG, MIR9-3.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–1): AC004882.1, AC004882.2, CABP7.
- chr22:46,684,410–46,738,252, 1 gene: CERK.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–37,477, 1 gene, copy number 5: AC215522.1.
- chr21:43,446,601–43,453,902, 1 gene, copy number 11: LINC00319.

Autosomal genes at a single copy (total copy number 1): 7,235. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
